TCGA case TCGA-RU-A8FL — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Northwestern University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5f6ed48b-3b5a-4d20-8fbf-c9aa3feea186

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 51 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.0; Tissue or organ of origin: Cecum; Site of resection or biopsy: Cecum; Classification of tumor: primary; Age at diagnosis: 52.0 years (18,975 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N2a; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,177 days (3.2 years).
   Pathology details: Circumferential resection margin: 65; Consistent pathology review: Yes; Lymph nodes positive: 5; Lymph nodes tested: 21; Non nodal tumor deposits: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Regimen or line of therapy: FOLFOX; Days to treatment start: 48 days; Days to treatment end: 210 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Days to treatment start: 270 days; Days to treatment end: 334 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium; Regimen or line of therapy: FOLFIRI; Days to treatment start: 270 days; Days to treatment end: 334 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab + Irinotecan; Days to treatment start: 343 days; Days to treatment end: 677 days (1.9 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium; Regimen or line of therapy: FOLFIRI; Days to treatment start: 679 days (1.9 years); Days to treatment end: 756 days (2.1 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Ziv-Aflibercept; Days to treatment start: 679 days (1.9 years); Days to treatment end: 756 days (2.1 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 788 days (2.2 years); Days to treatment end: 788 days (2.2 years); Treatment dose: 568 Gy; Treatment outcome: Stable Disease; Number of fractions: 5; Treatment anatomic sites: Distant Site.
2. Metastasis of diagnosis 1 (Adenocarcinoma, NOS), site: Liver. Age at diagnosis: 52.7 years (19,231 days); Days to diagnosis: 256 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 463 days (1.3 years); Treatment anatomic sites: Liver.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 463 days (1.3 years); Residual disease: R2; Treatment anatomic sites: Liver.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 256 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 256 days.
- Days to follow up: 921 days (2.5 years); Disease response: With Tumor.
- Days to follow up: 1,177 days (3.2 years); Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 24.6 ng/mL.
- KRAS mutation, nos: Negative.
- Microsatellite Instability: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 125 kg; Height: 187.96 cm; BMI: 35.4.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-RU-A8FL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 130 mg.
  Slide TCGA-RU-A8FL-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 7; Percent necrosis: 3; Percent stromal cells: 10; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-RU-A8FL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 24.6; Microsatellite instability: No; KRAS gene analysis indicator: Yes; KRAS mutation found: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: No; Treatment outcome first course: Partial Remission/Response.
- Drug treatment 1: Pharmaceutical therapy drug name: C1 FOLFIRI/Zaltrap; Treatment best response: Clinical Progressive Disease.
- Drug treatment 2: Pharmaceutical therapy drug name: Irinotecan + Cetuximab; Treatment best response: Clinical Progressive Disease.
- Drug treatment 3: Pharmaceutical therapy drug name: FOLFIRI/Avastin; Treatment best response: Clinical Progressive Disease.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,177 days; disease-specific survival: no event (censored), 1,177 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 256 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-RU-A8FL-01A-11D-A36W-01): tumor purity 0.72, ploidy 3.54, whole-genome doublings 1.
